Somatic mutation profile of tumor specimen TCGA-BK-A139-02A (aliquot TCGA-BK-A139-02A-11D-A27P-09) from TCGA case TCGA-BK-A139, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 74.1 years (27,077 days).
Specimen TCGA-BK-A139-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f369b983-0a40-42f2-b742-6932f98a3062.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BK-A139-10A (Blood Derived Normal), aliquot TCGA-BK-A139-10A-01D-A272-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28601cc7-31de-4a09-881e-a1da937d0de5

The open-access MAF lists 161 somatic variants for this specimen: 119 protein-altering or splice-affecting, 36 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 109, Silent 36, RNA 4, Nonsense Mutation 4, Splice Region 2, 5'UTR 2, Nonstop Mutation 1, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1717_1722del p.L573_R574del (on ENST00000521381 / NM_181523.3; = p.L303_R304del on NM_181504.4) | In Frame Del (DEL) | VAF 30/47 reads (64%) | hotspot (GDC flag); catalogued as COSV57129439; called by mutect2, pindel, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 15/27 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WDR45 | c.38G>C p.R13P | Missense Mutation (SNP) | VAF 39/613 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.269); catalogued as rs201177026, CS1211580, COSV100540084; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- ABCA4 | c.2477A>G p.N826S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV100933021; called by muse, mutect2, varscan2
- ADAMTS12 | c.4009A>G p.R1337G | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs1434307918, COSV100710274; called by muse, mutect2, varscan2
- ADAMTSL1 | c.808C>G p.P270A | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV99440869; called by muse, mutect2, varscan2
- ANKRD17 | c.4488A>T p.R1496S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.173); catalogued as COSV100428552; called by muse, mutect2, varscan2
- ANKRD17 | c.4487G>T p.R1496I | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.503); catalogued as COSV100428554; called by muse, mutect2, varscan2
- ASGR2 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs775565123, COSV54690086; called by muse, mutect2, varscan2
- ASH2L | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 62/110 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as COSV51698421; called by muse, mutect2, varscan2
- BSN | c.4183C>T p.R1395* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV99607231; called by muse, mutect2, varscan2
- BUB1 | c.1793G>A p.G598E | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.697); catalogued as COSV57067889; called by muse, mutect2, varscan2
- C18orf25 | c.647G>T p.S216I | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99959794; called by muse, mutect2, varscan2
- CAMKV | c.637C>T p.L213= | Splice Region (SNP) | VAF 22/48 reads (46%) | catalogued as rs200019805, COSV56555122; called by muse, mutect2, varscan2
- CBX6 | c.1085T>A p.M362K | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53320749; called by muse, mutect2, varscan2
- CCDC82 | c.1121T>C p.L374P | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1182611261, COSV53593198; called by muse, mutect2, varscan2
- CD5L | c.734G>C p.R245T | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100940992; called by muse, mutect2, varscan2
- CDADC1 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV51911319; called by muse, mutect2, varscan2
- CDH7 | c.1087A>T p.T363S | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV59885250; called by muse, mutect2, varscan2
- CFAP65 | c.2005C>G p.P669A | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.175); catalogued as COSV100444579; called by muse, mutect2, varscan2
- CGB1 | c.7A>T p.K3* | Nonsense Mutation (SNP) | VAF 37/169 reads (22%) | catalogued as COSV100031469; called by muse, mutect2, varscan2
- CIP2A | c.1336A>G p.T446A | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV99842621; called by muse, mutect2, varscan2
- COL13A1 | c.1013C>T p.A338V (on ENST00000398978 / NM_001130103.2; = p.A281V on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as rs1169446337, COSV62574015; called by muse, mutect2, varscan2
- COL9A2 | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.912); catalogued as rs199850925, COSV65622693; called by muse, mutect2, varscan2
- CPNE8 | c.1437G>A p.M479I | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1404165216, COSV58842313, COSV58848917; called by muse, mutect2, varscan2
- CSN2 | c.681A>C p.*227Yext*14 | Nonstop Mutation (SNP) | VAF 23/122 reads (19%) | catalogued as COSV100778720; called by muse, mutect2, varscan2
- DENND1C | c.2111C>A p.S704Y | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.06); catalogued as COSV100375161; called by muse, mutect2, varscan2
- DES | c.591G>T p.E197D | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV64660590; called by muse, mutect2, varscan2
- DGKA | c.351C>A p.F117L | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV100092626; called by muse, mutect2, varscan2
- DIAPH1 | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.562); catalogued as rs892261512, COSV53881689; called by muse, varscan2
- DMXL2 | c.3188G>C p.S1063T | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV51845230; called by muse, mutect2, varscan2
- DOCK7 | c.4833T>A p.F1611L (on ENST00000635253 / NM_001367561.1; = p.F1580L on NM_033407.3) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as COSV52003612; called by muse, mutect2, varscan2
- DSC2 | c.185A>G p.N62S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.034); catalogued as COSV51864126; called by muse, mutect2, varscan2
- DYNLRB1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as rs573896721, COSV64063820; called by muse, varscan2
- ELF5 | c.212A>T p.E71V (on ENST00000312319 / NM_198381.2; = p.E61V on NM_001422.4) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56628736; called by muse, mutect2, varscan2
- EPX | c.2125C>A p.L709I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99836219; called by muse, mutect2, varscan2
- EVC2 | c.231C>A p.D77E | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.014); catalogued as rs776531365, COSV60388298; called by muse, mutect2, varscan2
- EXOC5 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.607); catalogued as rs929476964, COSV100566959; called by muse, mutect2, varscan2
- FAM151B | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56472878; called by muse, mutect2, varscan2
- FAT1 | c.6488C>A p.A2163D | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV71673152, COSV71673571; called by muse, mutect2, varscan2
- FAT3 | c.4670A>G p.E1557G | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99961793; called by muse, mutect2, varscan2
- FAT4 | c.863G>T p.R288L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.257); catalogued as COSV101271835; called by muse, mutect2, varscan2
- FBXO5 | c.1018G>C p.D340H | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.215); catalogued as COSV99999666; called by muse, mutect2, varscan2
- FETUB | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54005465; called by muse, mutect2, varscan2
- FGF23 | c.704A>T p.H235L | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.026); catalogued as COSV99426220; called by muse, mutect2, varscan2
- FGL2 | c.1037A>G p.N346S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99592145; called by muse, mutect2, varscan2
- FILIP1L | c.142C>A p.L48I | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as COSV100496247, COSV58768243; called by muse, mutect2, varscan2
- FLG2 | c.4724G>T p.S1575I | Missense Mutation (SNP) | VAF 8/197 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV101165589; called by muse, mutect2
- FOXF2 | c.1327G>A p.V443I | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs181428616, COSV52525311; called by muse, mutect2, varscan2
- FOXR1 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs150635174, COSV57652017; called by muse, mutect2, varscan2
- FREM1 | c.2993C>G p.P998R | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); catalogued as COSV101083781; called by muse, mutect2, varscan2
- GDI1 | c.576C>A p.Y192* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99340838; called by muse, mutect2, varscan2
- GLA | c.556C>G p.H186D | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as COSV99516162; called by mutect2, varscan2
- GLI3 | c.4628C>G p.A1543G | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.701); catalogued as COSV67887890, COSV67895815; called by muse, mutect2, varscan2
- GPATCH2 | c.1324C>T p.R442W | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs775087701, COSV65131237; called by muse, mutect2, varscan2
- GSAP | c.2294G>T p.R765I | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs1201603617, COSV57529582; called by muse, mutect2, varscan2
- ITGB4 | c.1429G>A p.G477R | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370395920; called by muse, mutect2, varscan2
- KBTBD2 | c.448C>G p.Q150E | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100406377; called by muse, mutect2, varscan2
- KCNN1 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.229); catalogued as rs1260374056, COSV55838552; called by muse, mutect2, varscan2
- KCTD17 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63248902; called by muse, mutect2, varscan2
- KDM3B | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs1561770083, COSV58690112; called by muse, mutect2, varscan2
- KDR | c.686G>A p.S229N | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.023); catalogued as COSV55764064; called by muse, mutect2
- LAMA2 | c.3506T>G p.F1169C | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV101370000; called by muse, mutect2, varscan2
- LCE2B | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs767189385, COSV64227613; called by muse, mutect2, varscan2
- LGI4 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs144343503, COSV100032601; called by muse, mutect2, varscan2
- LONP2 | c.1464A>G p.I488M | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53522139; called by muse, mutect2, varscan2
- LRP2 | c.5734A>C p.T1912P | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as COSV99786500; called by muse, mutect2, varscan2
- LTBP4 | c.779G>C p.R260P (on ENST00000308370 / NM_001042544.1; = p.R223P on NM_003573.2) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99180389, COSV99192617; called by muse, mutect2, varscan2
- MAN2B1 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.85); catalogued as rs978130289, COSV55471928; called by muse, mutect2, varscan2
- MANBA | c.1360G>A p.G454R (on ENST00000642252; = p.G408R on NM_005908.4) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99898308; called by muse, mutect2, varscan2
- MAP4K3 | c.2028T>G p.C676W | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99809948; called by muse, mutect2, varscan2
- MELTF | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as rs755429699, COSV99585797; called by muse, mutect2, varscan2
- MKNK2 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.491); catalogued as COSV51732110; called by muse, mutect2, varscan2
- MTMR10 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV58727977; called by muse, mutect2, varscan2
- MTMR8 | c.1175C>G p.S392C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV66393605; called by muse, mutect2, varscan2
- MUC17 | c.6913G>T p.D2305Y | Missense Mutation (SNP) | VAF 99/159 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as COSV60287027; called by muse, mutect2, varscan2
- MYO1H | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764150151, COSV60443340; called by muse, mutect2, varscan2
- NRG1 | c.1451C>A p.P484Q (on ENST00000405005 / NM_013964.5; = p.P489Q on NM_013956.5) | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV55157105; called by muse, mutect2, varscan2
- OCIAD1 | c.244G>C p.A82P | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51900609; called by muse, mutect2, varscan2
- OR2B11 | c.51C>G p.I17M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV59510030; called by muse, mutect2, varscan2
- OR51E2 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs151286283; called by muse, mutect2, varscan2
- OR5B17 | c.253A>T p.I85L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV100641850; called by muse, mutect2, varscan2
- OR8K1 | c.715G>T p.G239W | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV54402287, COSV54403778; called by muse, mutect2, varscan2
- OR8U1 | c.541G>T p.D181Y | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as rs537232927, COSV100163763; called by muse, mutect2, varscan2
- OSMR | c.140G>T p.S47I | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV57084303; called by muse, varscan2
- PCNX4 | c.2882T>C p.I961T (on ENST00000406854 / NM_001330177.2; = p.I727T on NM_022495.5) | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV58303752; called by muse, mutect2, varscan2
- PRDM14 | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV52571980; called by muse, mutect2, varscan2
- PRPF19 | c.632C>A p.A211E | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV57128507, COSV99920449; called by muse, mutect2, varscan2
- PTCH1 | c.3070C>A p.L1024I | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100107462; called by muse, mutect2, varscan2
- RFX7 | c.1728G>C p.K576N (on ENST00000559447 / NM_001368074.1; = p.K673N on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.638); catalogued as COSV100428176; called by muse, mutect2, varscan2
- SDK1 | c.1513G>T p.G505W | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101268744, COSV67379246; called by mutect2, varscan2
- SIGLEC8 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.228); catalogued as rs746803267, COSV100367206, COSV58471655; called by muse, mutect2, varscan2
- SMR3A | c.45del p.C16Vfs*106 | Frame Shift Del (DEL) | VAF 31/145 reads (21%) | catalogued as COSV56949617, COSV56950143; called by mutect2, pindel, varscan2
- SNX7 | c.554T>C p.L185S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100068535; called by muse, mutect2, varscan2
- STAU2 | c.503G>C p.R168T (on ENST00000524300 / NM_001164380.2; = p.R136T on NM_014393.2) | Missense Mutation (SNP) | VAF 94/403 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100868992; called by muse, mutect2, varscan2
- STXBP5 | c.1844C>G p.T615R | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV99469134; called by muse, mutect2, varscan2
- SYCP2 | c.601A>T p.S201C | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100697961, COSV62766154; called by muse, mutect2, varscan2
- TECTA | c.1114G>T p.G372C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as COSV50703368; called by muse, mutect2, varscan2
- TENM3 | c.489A>C p.E163D | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.01); catalogued as COSV69306268; called by muse, mutect2, varscan2
- TJP3 | c.1110G>T p.Q370H | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.861); catalogued as COSV99515735; called by muse, mutect2
- TLL1 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV50275636, COSV50308643; called by muse, mutect2, varscan2
- TMC7 | c.652G>T p.V218L | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV58583118; called by muse, mutect2, varscan2
- TMEM204 | c.11A>C p.Q4P | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.244); catalogued as COSV99559685; called by muse, mutect2, varscan2
- TMEM47 | c.356T>A p.L119H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99327464; called by muse, varscan2
- TMEM70 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs747991849, COSV100383988; called by muse, mutect2
- TNR | c.1924C>A p.P642T | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.687); catalogued as COSV54897124; called by muse, mutect2, varscan2
- TRIM67 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs372382212, COSV64158042; called by muse, mutect2, varscan2
- TRIM69 | c.834T>C p.H278= (on ENST00000329464 / NM_182985.5; = p.H119= on NM_080745.5) | Splice Region (SNP) | VAF 34/89 reads (38%) | catalogued as rs1264818442, COSV57803580; called by muse, mutect2, varscan2
- TRMT9B | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs772918593, COSV101501514; called by muse, mutect2, varscan2
- TTC17 | c.190C>G p.H64D | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.942); catalogued as COSV50008171; called by muse, mutect2, varscan2
- XIRP2 | c.7142A>C p.E2381A (on ENST00000628543; = p.E2556A on NM_152381.6) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV54696516; called by mutect2, varscan2
- ZAN | c.7382A>C p.E2461A | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV100769133; called by muse, mutect2
- ZBTB24 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs761960881, COSV57781908; called by muse, mutect2, varscan2
- ZBTB38 | c.739A>G p.N247D | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV58541374; called by muse, mutect2, varscan2
- ZDHHC8 | c.1488C>A p.H496Q | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.097); catalogued as COSV100272600; called by muse, mutect2, varscan2
- ZNF254 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.467); catalogued as COSV60054126; called by muse, mutect2, varscan2
- ZNF324 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs766350436, COSV52181709; called by muse, mutect2, varscan2
- ZNF786 | c.1479G>T p.E493D | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV60275865; called by muse, mutect2, varscan2
- CASP8AP2 | c.5333dup p.A1779Gfs*13 | Frame Shift Ins (INS) | VAF 5/36 reads (14%) | called by mutect2, pindel, varscan2
- ACVR2A | c.1035A>G p.L345= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99603882; called by muse, mutect2, varscan2
- ANKRD30A | c.543G>A p.T181= (on ENST00000611781; = p.T125= on NM_052997.2) | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs748801395, COSV64609214, COSV64609913; called by mutect2, varscan2
- ARHGAP21 | c.4329G>A p.K1443= | Silent (SNP) | VAF 40/184 reads (22%) | catalogued as COSV100255754, COSV100256203; called by muse, mutect2, varscan2
- ARHGEF5 | c.4602C>T p.A1534= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs1040382186, COSV50209723; called by muse, mutect2, varscan2
- ASPM | c.234G>A p.K78= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV54128917; called by muse, mutect2, varscan2
- BBS5 | c.213C>A p.V71= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as COSV99751610; called by muse, mutect2, varscan2
- CACNB2 | c.858A>G p.L286= (on ENST00000324631 / NM_201596.3; = p.L231= on NM_000724.4) | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV56621483; called by muse, mutect2, varscan2
- CCDC9B | c.936C>T p.G312= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs563889496, COSV66876044; called by muse, mutect2, varscan2
- CD5 | c.1122C>A p.G374= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100759739; called by muse, mutect2, varscan2
- COL6A1 | c.357G>A p.A119= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs747037863, COSV62612876, COSV62614791; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DDX24 | c.1680G>A p.V560= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as rs767350697, COSV58212349; called by muse, mutect2, varscan2
- DHRS7C | c.840C>T p.P280= (on ENST00000330255 / NM_001220493.2; = p.P279= on NM_001105571.3) | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV57650551; called by muse, mutect2, varscan2
- DNM2 | c.1143G>A p.E381= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV58960896; called by muse, mutect2, varscan2
- GCLM | c.753G>A p.S251= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs567112849, COSV64686989; called by muse, mutect2, varscan2
- KPTN | c.640C>A p.R214= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV57645017; called by muse, mutect2, varscan2
- KRT85 | c.1479C>T p.S493= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV99225122; called by muse, mutect2, varscan2
- KRTAP4-4 | c.357C>T p.T119= | Silent (SNP) | VAF 28/169 reads (17%) | catalogued as rs367733349, COSV101180527; called by muse, mutect2, varscan2
- LAMA2 | c.5937C>T p.N1979= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs747714599, COSV70345709; called by muse, mutect2, varscan2
- NUP98 | c.3672A>G p.K1224= (on ENST00000359171 / NM_001365126.1; = p.K1207= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV61428998; called by muse, mutect2, varscan2
- PAPPA | c.3480G>A p.Q1160= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV60282159; called by muse, mutect2, varscan2
- PASK | c.2853C>G p.P951= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as COSV99298622; called by muse, mutect2, varscan2
- PIK3C2B | c.2958G>C p.L986= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV100915978, COSV65810211, COSV65812471; called by muse, mutect2, varscan2
- PIK3C2B | c.2142C>A p.I714= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV100915979, COSV100916055, COSV65811405; called by muse, mutect2, varscan2
- PRKDC | c.6483G>A p.A2161= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs761604517, COSV100038376, COSV100041023; called by muse, mutect2
- PSPC1 | c.504C>T p.S168= | Silent (SNP) | VAF 37/68 reads (54%) | catalogued as COSV58887893; called by muse, mutect2, varscan2
- ROBO4 | c.228C>A p.P76= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV100127291; called by muse, mutect2, varscan2
- SCN5A | c.1380C>T p.S460= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV61122478; called by muse, mutect2, varscan2
- SNAP47 | c.714G>A p.R238= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV100247912; called by muse, mutect2, varscan2
- SOWAHB | c.111C>G p.P37= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV57554295, COSV57554402; called by muse, mutect2, varscan2
- SUZ12 | c.546T>C p.V182= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV59499700; called by muse, mutect2, varscan2
- TCF3 | c.474G>C p.R158= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs755980732, COSV99513550; called by muse, mutect2
- TEKT2 | c.912G>T p.L304= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as COSV52880871; called by muse, mutect2, varscan2
- TTL | c.123G>A p.L41= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV51974322; called by muse, mutect2, varscan2
- TUBB8 | c.1206C>T p.G402= | Silent (SNP) | VAF 18/127 reads (14%) | catalogued as rs781835855, COSV100225902; called by muse, mutect2, varscan2
- VIL1 | c.627C>T p.G209= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs767787005, COSV50287346; called by muse, mutect2, varscan2
- ZFC3H1 | c.1762T>C p.L588= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV66432066; called by muse, mutect2, varscan2
- OR2W5 | n.945C>A | RNA (SNP) | VAF 21/126 reads (17%) | called by muse, mutect2, varscan2
- SNORD115-17 | n.20T>C | RNA (SNP) | VAF 26/92 reads (28%) | called by muse, mutect2, varscan2
- SNORD115-26 | n.80C>G | RNA (SNP) | VAF 17/63 reads (27%) | catalogued as rs1309797844; called by muse, mutect2, varscan2
- SSPOP | n.5698G>A | RNA (SNP) | VAF 17/44 reads (39%) | catalogued as rs766327797, COSV50487245; called by muse, mutect2, varscan2
- TSPAN6 | c.-1C>T | 5'UTR (SNP) | VAF 17/56 reads (30%) | catalogued as COSV100885744; called by muse, mutect2, varscan2
- ZNF324B | c.-38C>G | 5'UTR (SNP) | VAF 14/56 reads (25%) | catalogued as COSV100351512; called by muse, mutect2, varscan2
